Somatic mutation profile of tumor specimen TCGA-22-1005-01A (aliquot TCGA-22-1005-01A-01D-1521-08) from TCGA case TCGA-22-1005, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.9 years (23,322 days).
Specimen TCGA-22-1005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2cb0f5e-c369-4f95-bd6d-593d42d87b40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1005-11A (Solid Tissue Normal), aliquot TCGA-22-1005-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcb05efe-284c-4efa-a770-233a542ead9f

The open-access MAF lists 264 somatic variants for this specimen: 194 protein-altering or splice-affecting, 64 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 64, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 3, 3'UTR 2, Intron 2, RNA 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1700T>G p.L567R (on ENST00000404938 / NM_001163941.2; = p.L122R on NM_178559.6) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99327916, COSV99329706; called by muse, mutect2, varscan2
- ACSM2B | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100312502; called by muse, mutect2
- ADAD1 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.325); catalogued as COSV56644668, COSV99635370; called by muse, mutect2, varscan2
- ADAMTS12 | c.2468A>G p.Q823R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100710576; called by muse, mutect2, varscan2
- AGBL2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 17/178 reads (10%) | catalogued as COSV100101504, COSV54092129; called by muse, mutect2
- AGTRAP | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100065257; called by muse, mutect2
- AHDC1 | c.2228G>T p.R743L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55937704, COSV55941138; called by muse, mutect2
- AHNAK | c.13121A>T p.K4374M | Missense Mutation (SNP) | VAF 34/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946603; called by muse, mutect2, varscan2
- AL645922.1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99067267; called by muse, mutect2
- ALDH1L2 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99310851; called by muse, mutect2
- AMER3 | c.1366C>A p.P456T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100366277; called by muse, mutect2
- AMPH | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100341542; called by muse, mutect2
- ARL6 | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.807); catalogued as rs541850084, COSV100256431; called by muse, mutect2, varscan2
- ARPP21 | c.2135C>G p.P712R | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV99491561; called by muse, mutect2
- ARSG | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71592387; called by muse, mutect2
- ATF2 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV99908581; called by muse, mutect2
- ATP6V0A4 | c.242T>A p.L81H | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.643); catalogued as COSV100022933; called by muse, mutect2
- BLK | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as rs1284697634, COSV99377045; called by muse, mutect2
- C9orf135 | c.437A>C p.D146A | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101019794; called by muse, mutect2
- CABP7 | c.426C>A p.C142* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53363135, COSV99334744; called by muse, mutect2, varscan2
- CACNA1B | c.3190G>A p.V1064I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1300134377, COSV53141285; called by muse, mutect2
- CACNA1G | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100661564; called by muse, mutect2, varscan2
- CCDC60 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 30/521 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.316); catalogued as COSV100554885, COSV59552269; called by muse, mutect2
- CCHCR1 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100885607; called by muse, mutect2, varscan2
- CD84 | c.389-1G>A p.X130_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as rs1328390115, COSV100245914; called by muse, mutect2, varscan2
- CELF3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99310172; called by muse, mutect2, varscan2
- CEP290 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100468260; called by muse, mutect2
- CLDN25 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.707); catalogued as COSV101493589; called by muse, mutect2
- CLEC14A | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV60563792; called by muse, mutect2
- CLIP4 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs771314138, COSV100191697; called by muse, mutect2
- COL11A2 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.394); catalogued as rs768676077, COSV100553700; called by muse, mutect2
- COL5A2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100880132; called by muse, mutect2
- CPNE7 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99254689; called by muse, mutect2, varscan2
- CPSF3 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV99432664; called by muse, mutect2
- CPSF3 | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as COSV99432668; called by muse, mutect2
- CYB5R4 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV100859648; called by muse, mutect2
- CYLC1 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV100254352; called by muse, mutect2, varscan2
- DHX9 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100841333, COSV62361587; called by muse, mutect2
- DMTF1 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100487334; called by muse, mutect2
- DNAH8 | c.2291G>C p.S764T | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as COSV100544151; called by muse, mutect2
- DNAJC5G | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.725); catalogued as COSV99940518; called by muse, mutect2
- EARS2 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101492154; called by muse, mutect2
- EBP | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1556977736, COSV99339315; called by muse, mutect2, varscan2
- EIF2B5 | c.939G>C p.M313I (on ENST00000647909; = p.M305I on NM_003907.3) | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as CM152486, COSV99889122; called by muse, mutect2
- ERC1 | c.2220G>C p.L740F (on ENST00000360905 / NM_178040.4; = p.L712F on NM_178039.4) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100705827; called by muse, mutect2
- ERCC3 | c.2027G>T p.R676L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99573196, COSV99573204; called by muse, mutect2
- FAM160A2 | c.2548G>T p.D850Y (on ENST00000449352 / NM_001098794.2; = p.D864Y on NM_032127.4) | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56413336; called by muse, mutect2
- FLG | c.10462C>G p.Q3488E | Missense Mutation (SNP) | VAF 78/729 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV100911361, COSV64235923; called by muse, mutect2, varscan2
- FMO2 | c.1100C>A p.A367E | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99269034; called by muse, mutect2, varscan2
- FNTA | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 17/289 reads (6%) | catalogued as COSV100172474; called by muse, mutect2
- FOXM1 | c.635T>A p.L212Q | Missense Mutation (SNP) | VAF 80/864 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); catalogued as COSV100700819, COSV100700844; called by muse, mutect2
- FSD2 | c.1026A>T p.E342D | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100575075; called by muse, mutect2
- FYTTD1 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs771710665, COSV99611454; called by muse, mutect2
- GABRA6 | c.459T>A p.N153K | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV99194208; called by muse, mutect2
- GANC | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 8/202 reads (4%) | PolyPhen benign (0); catalogued as rs983406580, COSV100530675; called by muse, mutect2
- GAPDHS | c.489C>A p.S163R | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV99722267; called by muse, mutect2, varscan2
- GLG1 | c.1190G>T p.R397M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99215567; called by muse, mutect2, varscan2
- GLRA2 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99490644; called by muse, mutect2
- GPR61 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV101344402, COSV68177294; called by muse, mutect2
- GRID1 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 15/200 reads (8%) | catalogued as COSV100023152; called by muse, mutect2
- GRM1 | c.1891T>A p.C631S | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV99265213; called by muse, mutect2
- HEPACAM2 | c.886G>T p.G296W (on ENST00000394468 / NM_001039372.4; = p.G284W on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506471; called by muse, mutect2, varscan2
- HOXB13 | c.703T>C p.Y235H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99284831; called by muse, mutect2
- HTR7 | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99519284; called by muse, mutect2
- IGFBP1 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1029772778, COSV99298692; called by muse, mutect2
- IMPG2 | c.3090G>T p.W1030C | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99515181; called by muse, mutect2
- ISM2 | c.588G>T p.L196F | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV99376543; called by muse, mutect2
- ITGA8 | c.2030G>C p.R677T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV100958948, COSV100959068, COSV65227346; called by muse, mutect2
- ITPR1 | c.7142G>A p.R2381K (on ENST00000354582; = p.R2326K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.99); catalogued as rs1343639552, COSV100230554; called by muse, mutect2
- KCNC2 | c.1492C>A p.P498T | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100128530, COSV54381444; called by muse, mutect2
- KCNH4 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV52917960; called by muse, mutect2, varscan2
- KCNJ15 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100154119, COSV60812268; called by muse, mutect2
- KDM5C | c.3413A>C p.Q1138P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100948977; called by muse, mutect2
- KIF1A | c.4601C>A p.P1534H (on ENST00000320389 / NM_001379639.1; = p.P1526H on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100240384; called by mutect2, varscan2
- KIF5A | c.2450C>A p.P817H | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV54058630; called by muse, mutect2
- KLK15 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1568483222, COSV56825742, COSV56827015; called by muse, varscan2
- KRT25 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100379870; called by muse, mutect2
- KRT4 | c.1217C>G p.A406G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV53407800, COSV99542797; called by muse, mutect2
- LRRTM3 | c.71T>A p.L24Q | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100791566; called by muse, mutect2
- MAPK4 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101245289; called by muse, mutect2, varscan2
- MARCHF11 | c.1122G>T p.L374F | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs201724441, COSV100197677; called by muse, mutect2
- MARK3 | c.767A>C p.Q256P | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99358069; called by muse, mutect2
- MAST2 | c.2105A>G p.Y702C | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100787972; called by muse, mutect2, varscan2
- MFSD11 | c.874+1G>A p.X292_splice | Splice Site (SNP) | VAF 14/231 reads (6%) | catalogued as COSV100333690; called by muse, mutect2
- MFSD6 | c.771G>T p.K257N | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99855114; called by muse, mutect2
- MRPS22 | c.861G>T p.Q287H (on ENST00000310776 / NM_001363893.1; = p.Q288H on NM_020191.4) | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV60351132; called by muse, mutect2
- MUC5AC | c.16343T>A p.V5448E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100611389; called by muse, mutect2, varscan2
- MXRA5 | c.2903C>G p.S968C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.431); catalogued as COSV54252354, COSV99476336; called by muse, mutect2, varscan2
- MYBPC1 | c.1996T>C p.W666R (on ENST00000550270 / NM_206820.2; = p.W691R on NM_002465.4) | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637860; called by muse, mutect2
- MYH13 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99353221; called by muse, mutect2, varscan2
- MYO16 | c.3130C>A p.P1044T | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100696488; called by muse, mutect2
- MYO1A | c.1141A>T p.I381F | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100270804; called by muse, mutect2
- MYT1L | c.954C>A p.S318R | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as rs142499159, COSV101219802; called by muse, mutect2
- NAALAD2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100428220; called by muse, mutect2
- NBAS | c.5037G>T p.E1679D | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV99868472; called by muse, mutect2
- NECTIN1 | c.1048G>T p.G350W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as COSV99871947; called by mutect2, varscan2
- NFASC | c.1272T>G p.S424R (on ENST00000339876 / NM_001378329.1; = p.S435R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100363381; called by muse, mutect2
- NLRP13 | c.2575T>C p.C859R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.758); catalogued as COSV100738121; called by muse, mutect2
- NLRP3 | c.2708C>A p.S903Y | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100275673; called by muse, mutect2
- NLRP4 | c.1173A>T p.Q391H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100015985; called by muse, mutect2, varscan2
- NUDT6 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1311747884, COSV99915102; called by muse, mutect2
- OGT | c.2250T>A p.D750E | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV101035294; called by muse, mutect2, varscan2
- OR10G7 | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV100389860; called by muse, mutect2
- OR2F1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 52/670 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1021140513, COSV67331305; called by muse, mutect2
- OR2T11 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.063); catalogued as COSV100424748; called by muse, mutect2
- OR2V2 | c.319T>G p.C107G | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100080066; called by muse, mutect2
- OR4N5 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 41/690 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100374074, COSV61321295; called by muse, mutect2
- OR4P4 | c.708del p.T237Lfs*6 | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | catalogued as COSV58922443; called by mutect2, pindel, varscan2
- OR5T2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57588702; called by muse, mutect2
- OR6F1 | c.631T>C p.C211R | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100129066; called by muse, mutect2
- OR6K6 | c.422G>A p.C141Y (on ENST00000368144; = p.C117Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100933718; called by muse, mutect2
- OR8K3 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs879271350; called by muse, mutect2
- OR9I1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs146574837, COSV100109678; called by muse, mutect2
- P4HA3 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100525645; called by muse, mutect2
- PCDH15 | c.4846C>A p.R1616S (on ENST00000644397 / NM_001354429.2; = p.R1558S on NM_001142771.2) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV64748941; called by muse, mutect2, varscan2
- PCDH15 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218222; called by muse, mutect2
- PCDH15 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57372938; called by muse, mutect2
- PCDHGA11 | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99534678; called by muse, mutect2
- PEG3 | c.3262G>T p.V1088F | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.942); catalogued as COSV55630903, COSV55633895; called by muse, mutect2
- PGK2 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100505400, COSV59163877; called by muse, mutect2
- PHLDA3 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.987); catalogued as COSV100943598; called by muse, mutect2
- PIK3CA | c.899A>T p.D300V | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99835872; called by muse, mutect2
- PLA2G2F | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV100907902; called by muse, mutect2
- PLEKHG1 | c.4070T>A p.L1357H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100651554, COSV62051136; called by muse, mutect2
- PLS1 | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV100538038; called by muse, mutect2
- PNMA8B | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100885368; called by muse, mutect2
- POLQ | c.7399C>G p.Q2467E | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99951974; called by muse, mutect2
- PPFIA1 | c.2176A>G p.R726G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99557175; called by muse, mutect2
- PPIP5K2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV100383618, COSV100383777; called by muse, mutect2
- PREX1 | c.2905C>A p.P969T | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906147; called by muse, mutect2
- PSG4 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV99736718; called by muse, mutect2, varscan2
- RBBP8NL | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99436446; called by muse, mutect2
- RELN | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as rs563525929, COSV100633132; called by muse, mutect2
- RFX4 | c.1347C>A p.S449R (on ENST00000392842 / NM_213594.3; = p.S355R on NM_032491.6) | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99985608; called by muse, mutect2
- RIMS1 | c.1808A>G p.N603S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.056); catalogued as COSV53451580; called by muse, mutect2
- RIN1 | c.1593G>T p.G531= | Splice Region (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100254478; called by muse, mutect2
- RP1 | c.3548T>C p.V1183A | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1333490046, COSV99606914; called by muse, mutect2
- RUBCN | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | catalogued as COSV99583663; called by muse, mutect2
- SCG2 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100544661; called by muse, mutect2
- SCN1A | c.2044-1G>T p.X682_splice (on ENST00000303395 / NM_001202435.3; = p.X671_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/120 reads (7%) | catalogued as CS144083, COSV100319902; called by muse, mutect2
- SCYL2 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100675132; called by muse, mutect2
- SEC24C | c.1039A>C p.T347P | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100226671; called by muse, mutect2, varscan2
- SEMA3D | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99406276; called by muse, mutect2
- SGMS1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.412); catalogued as COSV62370559; called by muse, mutect2
- SLC12A5 | c.1559G>C p.G520A (on ENST00000454036 / NM_001134771.2; = p.G497A on NM_020708.5) | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54796023, COSV99715680; called by muse, mutect2
- SLC35G1 | c.314G>T p.C105F (on ENST00000427197 / NM_001134658.3; = p.C104F on NM_153226.4) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.525); catalogued as COSV101004042; called by muse, mutect2
- SLC39A3 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.474); catalogued as COSV54119185, COSV99514152; called by muse, mutect2, varscan2
- SLC7A13 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99878709; called by muse, mutect2, varscan2
- SLIT1 | c.3337T>A p.Y1113N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV99821028; called by muse, mutect2, varscan2
- SMARCA2 | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1331151656, COSV100570636; called by muse, mutect2, varscan2
- SMG1 | c.9441G>T p.Q3147H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101245544, COSV67174827; called by muse, mutect2
- SNRNP35 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 12/201 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as COSV100644554; called by muse, mutect2
- SPEG | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs758102466, COSV56672549; called by muse, mutect2
- STAB2 | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101185784; called by muse, mutect2
- SZT2 | c.8792T>G p.L2931R (on ENST00000634258 / NM_001365999.1; = p.L2874R on NM_015284.4) | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100987025; called by muse, mutect2
- TARS1 | c.1570A>G p.N524D | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99465722; called by muse, mutect2, varscan2
- TDG | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99904122; called by muse, mutect2
- TGM5 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 25/228 reads (11%) | catalogued as COSV99588856, COSV99589405; called by muse, mutect2, varscan2
- TLR3 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57170842; called by muse, mutect2, varscan2
- TMEM100 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 19/267 reads (7%) | catalogued as COSV101448217, COSV70117897; called by muse, mutect2
- TMEM255B | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100943114; called by muse, mutect2, varscan2
- TMEM74B | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV101121964; called by muse, mutect2
- TMPRSS4 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101449366; called by muse, mutect2
- TNC | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100405410; called by muse, mutect2
- TP53BP2 | c.3326A>G p.N1109S (on ENST00000343537 / NM_001031685.3; = p.N980S on NM_005426.2) | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100636557, COSV59066887; called by muse, mutect2
- TRIM55 | c.635G>T p.C212F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99396684; called by muse, mutect2, varscan2
- TRPC5 | c.353A>C p.Y118S | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV99460138; called by muse, mutect2, varscan2
- TUT4 | c.4421A>G p.Y1474C | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1183261400, COSV99932050; called by muse, mutect2
- TXNL4A | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99511400; called by muse, mutect2, varscan2
- USP13 | c.1729T>G p.F577V | Missense Mutation (SNP) | VAF 18/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830962; called by muse, mutect2
- USP9Y | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100168274; called by muse, mutect2, varscan2
- VWA5A | c.1389G>T p.Q463H | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV100827803, COSV100827943; called by muse, mutect2
- WDFY3 | c.9685C>T p.Q3229* | Nonsense Mutation (SNP) | VAF 12/209 reads (6%) | catalogued as COSV99882853; called by muse, mutect2
- XRCC2 | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1382942740, COSV100831598; called by muse, mutect2
- YIF1B | c.786C>A p.F262L (on ENST00000339413 / NM_001039673.3; = p.F247L on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100007851; called by muse, mutect2, varscan2
- ZBTB41 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); catalogued as COSV100962987, COSV66359158; called by muse, mutect2
- ZCRB1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV99861222; called by muse, mutect2
- ZNF283 | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100161349; called by muse, mutect2, varscan2
- ZNF354C | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 13/208 reads (6%) | catalogued as COSV100203566; called by muse, mutect2
- ZNF571 | c.1352A>C p.E451A | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100143656, COSV100143698; called by muse, mutect2
- ZNF609 | c.862G>C p.G288R | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100440727; called by muse, mutect2
- ZNF99 | c.2299G>T p.G767C | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101233779; called by muse, mutect2
- ZSCAN9 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs941676970, COSV52849899, COSV52851227; called by muse, mutect2
- BOC | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2
- FLNC | c.2975G>T p.G992V | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HS3ST4 | c.1088_1105del p.D363_M368del | In Frame Del (DEL) | VAF 66/371 reads (18%) | called by mutect2, pindel
- HSPBP1 | c.496del p.A166Hfs*70 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- KCNH5 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); called by muse, mutect2
- LNX1 | c.926A>T p.D309V (on ENST00000263925 / NM_001126328.3; = p.D213V on NM_032622.2) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYO19 | c.2125C>T p.Q709* (on ENST00000614623 / NM_001163735.1; = p.Q509* on NM_025109.5) | Nonsense Mutation (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- NOP9 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- SPATA31A1 | c.3536A>T p.K1179I | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- TOMM40 | c.535del p.Q179Rfs*8 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- UBAC2 | c.873G>T p.Q291H (on ENST00000403766 / NM_001144072.2; = p.Q256H on NM_177967.4) | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- AAR2 | c.585A>T p.L195= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV100299232, COSV57924522; called by muse, mutect2
- ADAM21 | c.1746C>T p.H582= | Silent (SNP) | VAF 15/215 reads (7%) | catalogued as COSV99960749; called by muse, mutect2
- ADAMTS12 | c.1812G>T p.R604= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as COSV100710578; called by muse, mutect2, varscan2
- AGGF1 | c.942A>T p.A314= | Silent (SNP) | VAF 22/308 reads (7%) | catalogued as COSV100461681; called by muse, mutect2
- C11orf24 | c.759A>G p.A253= | Silent (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- CAD | c.2364G>C p.V788= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99254756; called by muse, mutect2
- CCDC42 | c.7C>T p.L3= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV99549739; called by muse, mutect2, varscan2
- CDH23 | c.1401C>A p.I467= | Silent (SNP) | VAF 20/301 reads (7%) | catalogued as COSV99820011; called by muse, mutect2
- CHRM2 | c.72G>T p.V24= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as COSV57772292; called by muse, mutect2
- CHRM3 | c.1494T>A p.L498= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV99697954; called by muse, mutect2
- CHST8 | c.504G>T p.R168= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52858171, COSV99380922; called by muse, mutect2, varscan2
- CIBAR1 | c.790C>A p.R264= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100844648; called by muse, mutect2, varscan2
- CTNNA3 | c.2173C>T p.L725= | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as COSV101041325; called by muse, mutect2
- CYTIP | c.783C>T p.Y261= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99938695; called by muse, mutect2
- DAP3 | c.615A>G p.Q205= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV100546425; called by muse, mutect2
- DENND4A | c.3132C>A p.L1044= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV71265790; called by muse, mutect2
- DMD | c.7575C>T p.P2525= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- FBXO38 | c.3333A>G p.L1111= (on ENST00000340253 / NM_205836.3; = p.L1036= on NM_030793.5) | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV99693284; called by muse, mutect2
- GAS2L2 | c.1536C>T p.P512= | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- GLB1 | c.597C>T p.Y199= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs1404645663, COSV100257139; called by muse, mutect2, varscan2
- GPI | c.1341G>A p.K447= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV100731489; called by muse, mutect2
- GPR158 | c.1143T>C p.S381= | Silent (SNP) | VAF 18/275 reads (7%) | catalogued as rs775055353, COSV100893134; called by muse, mutect2
- GRIN2B | c.3069G>A p.L1023= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV101662988; called by muse, mutect2
- GRM1 | c.2910G>A p.P970= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs760312188, COSV51109833; called by muse, mutect2
- GUCY2D | c.1095G>T p.R365= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99643877; called by muse, mutect2, varscan2
- HTR1A | c.141C>A p.I47= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100109014, COSV60499920; called by muse, mutect2, varscan2
- ITGAD | c.2193C>T p.L731= | Silent (SNP) | VAF 9/241 reads (4%) | catalogued as rs1403665339, COSV66760421; called by muse, mutect2
- IWS1 | c.2334G>A p.Q778= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV99767113; called by muse, mutect2, varscan2
- KMT2B | c.5917C>T p.L1973= | Silent (SNP) | VAF 11/129 reads (9%) | catalogued as rs755692175, COSV99719226; called by muse, mutect2
- KRT38 | c.999G>A p.E333= | Silent (SNP) | VAF 11/185 reads (6%) | catalogued as rs1407473926, COSV99878150; called by muse, mutect2
- LAMB4 | c.4509G>T p.A1503= | Silent (SNP) | VAF 30/359 reads (8%) | catalogued as COSV99223502, COSV99225418; called by muse, mutect2
- LRP8 | c.2862A>C p.A954= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV100036266; called by muse, mutect2
- MARK4 | c.105C>T p.S35= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99488120; called by muse, mutect2
- MLXIPL | c.1842A>T p.S614= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- NAV3 | c.6711C>A p.T2237= (on ENST00000397909 / NM_001024383.2; = p.T2215= on NM_014903.6) | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV99888930; called by muse, mutect2
- NECTIN2 | c.873C>G p.P291= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as COSV99374877; called by muse, mutect2, varscan2
- NES | c.2862G>T p.T954= | Silent (SNP) | VAF 43/454 reads (9%) | catalogued as COSV100957818; called by muse, mutect2
- NRCAM | c.3354G>T p.R1118= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100694522; called by muse, mutect2, varscan2
- OR4K5 | c.492G>T p.V164= | Silent (SNP) | VAF 37/584 reads (6%) | catalogued as COSV100262264, COSV60005342; called by muse, mutect2
- PAK3 | c.1449C>T p.L483= (on ENST00000262836 / NM_001324328.2; = p.L468= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV53279618; called by muse, mutect2
- PELO | c.573G>A p.Q191= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV99251023; called by muse, mutect2
- PLAC8 | c.153G>T p.G51= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV100274466; called by muse, mutect2
- POM121 | c.1026C>G p.R342= (on ENST00000434423; = p.R77= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/577 reads (7%) | catalogued as COSV99987963; called by muse, mutect2
- PRR14L | c.5640G>T p.S1880= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as COSV100392248; called by muse, mutect2
- PVR | c.918C>T p.I306= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV99495723; called by muse, mutect2, varscan2
- RERE | c.543C>T p.L181= | Silent (SNP) | VAF 9/163 reads (6%) | catalogued as COSV100555786; called by muse, mutect2
- SARS1 | c.1368G>A p.L456= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV99321093; called by muse, mutect2
- SCRN1 | c.645G>T p.T215= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as COSV54133141; called by muse, mutect2
- SEMA5A | c.552C>A p.A184= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV101227605; called by muse, mutect2, varscan2
- SEMA7A | c.561G>A p.V187= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as COSV99984677; called by muse, mutect2
- SLC12A5 | c.1749C>A p.I583= (on ENST00000454036 / NM_001134771.2; = p.I560= on NM_020708.5) | Silent (SNP) | VAF 25/331 reads (8%) | catalogued as rs752463505, COSV99715684; called by muse, mutect2
- SLIT1 | c.3336C>T p.G1112= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs776045110, COSV99821034; called by mutect2, varscan2
- SORL1 | c.4155A>G p.R1385= | Silent (SNP) | VAF 33/412 reads (8%) | catalogued as COSV99493346; called by muse, mutect2
- SPATA5L1 | c.1542G>T p.L514= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV99972963; called by muse, mutect2, varscan2
- SPHK2 | c.1518C>T p.A506= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99709257; called by muse, mutect2
- SRMS | c.627G>A p.L209= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV99421252; called by muse, mutect2
- TECTA | c.2592C>T p.N864= | Silent (SNP) | VAF 22/239 reads (9%) | catalogued as rs377433816, CM054139; called by muse, mutect2
- TRPM1 | c.3768G>T p.T1256= | Silent (SNP) | VAF 13/183 reads (7%) | catalogued as COSV99855677; called by muse, mutect2
- TTC16 | c.477C>T p.F159= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV58853182; called by muse, mutect2
- TULP1 | c.732C>T p.G244= | Silent (SNP) | VAF 46/605 reads (8%) | catalogued as rs201670161, COSV100004021; called by muse, mutect2
- VWA3B | c.393G>A p.R131= | Silent (SNP) | VAF 25/410 reads (6%) | catalogued as COSV68240674; called by muse, mutect2
- ZBTB38 | c.3201C>T p.V1067= | Silent (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100375519; called by muse, mutect2
- ZNF254 | c.72G>T p.L24= | Silent (SNP) | VAF 14/282 reads (5%) | catalogued as COSV100298151; called by muse, mutect2
- ZPLD1 | c.96T>C p.S32= (on ENST00000466937 / NM_001329788.1; = p.S48= on NM_175056.2) | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100083073; called by muse, mutect2
- C7orf66 | n.385A>T | RNA (SNP) | VAF 19/174 reads (11%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1156G>T | 3'UTR (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99601229; called by muse, mutect2, varscan2
- KNOP1P1 | n.123C>A | RNA (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- NEBL | c.164+46504G>T | Intron (SNP) | VAF 19/376 reads (5%) | catalogued as COSV101008755; called by muse, mutect2
- PDE4D | c.455+306839G>T | Intron (SNP) | VAF 30/496 reads (6%) | catalogued as COSV100505982; called by muse, mutect2
- SEC63 | c.*1G>A | 3'UTR (SNP) | VAF 19/416 reads (5%) | catalogued as COSV100938350; called by muse, mutect2
